Somatic mutation profile of tumor specimen MMRF_2043_1_BM_CD138pos (aliquot MMRF_2043_1_BM_CD138pos_T1_KHS5U_L08144) from MMRF case MMRF_2043, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 70.6 years (25,790 days).
Specimen MMRF_2043_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2bcad219-48ef-430a-aaca-c7a5e2183b47.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2043_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2043_1_PB_Whole_C2_KHS5U_L08145; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3a3fa019-6063-4db4-abb1-57a9cc2927be

The open-access MAF lists 108 somatic variants for this specimen: 45 protein-altering or splice-affecting, 20 silent, 43 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 42, 3'UTR 24, Silent 20, Intron 10, 5'UTR 4, 5'Flank 2, Frame Shift Del 2, RNA 2, 3'Flank 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASB14 | c.433A>G p.N145D (on ENST00000389601; = p.N144D on NM_001142733.3) | Missense Mutation (SNP) | VAF 75/132 reads (57%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as rs117818627; called by muse, mutect2, varscan2
- CAAP1 | c.287C>T p.S96L | Missense Mutation (SNP) | VAF 23/110 reads (21%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); catalogued as COSV100445345; called by muse, mutect2, varscan2
- CDHR2 | c.3149G>A p.R1050Q | Missense Mutation (SNP) | VAF 114/403 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.46); catalogued as rs761381922; called by muse, mutect2, varscan2
- CDK5 | c.463G>A p.V155I | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.014); catalogued as rs763122603; called by muse, mutect2, varscan2
- CHSY1 | c.1153T>C p.Y385H | Missense Mutation (SNP) | VAF 55/239 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV54254446; called by muse, mutect2, varscan2
- FAHD1 | c.710C>T p.P237L | Missense Mutation (SNP) | VAF 97/209 reads (46%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.011); catalogued as rs528391738; called by muse, mutect2, varscan2
- IGHV2-70 | c.244A>C p.T82P | Missense Mutation (SNP) | VAF 52/80 reads (65%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs375530938; called by muse, varscan2
- IGLV3-1 | c.131A>G p.D44G | Missense Mutation (SNP) | VAF 59/142 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.027); catalogued as rs774199094; called by muse, varscan2
- IL22RA1 | c.227G>A p.R76Q | Missense Mutation (SNP) | VAF 50/155 reads (32%) | SIFT tolerated (0.84); PolyPhen benign (0.006); catalogued as rs781318907; called by muse, mutect2, varscan2
- KIF21A | c.3028A>G p.I1010V (on ENST00000361418 / NM_001378440.1; = p.I997V on NM_017641.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/81 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.371); catalogued as rs751836346; called by muse, mutect2, varscan2
- KLK7 | c.166G>A p.G56R | Missense Mutation (SNP) | VAF 9/104 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58344395; called by muse, mutect2
- KPRP | c.358G>A p.V120M | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as rs749198811; called by muse, mutect2
- LOX | c.1220C>T p.A407V | Missense Mutation (SNP) | VAF 6/136 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.172); catalogued as rs1478649419, COSV50240688; called by muse, mutect2
- NDST3 | c.1583G>A p.R528Q | Missense Mutation (SNP) | VAF 19/235 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.173); catalogued as rs777809733; called by muse, mutect2
- PIM1 | c.286G>A p.V96M | Missense Mutation (SNP) | VAF 70/170 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.438); catalogued as COSV65164628, COSV65165383, COSV65165412; called by muse, mutect2, varscan2
- RYR2 | c.6593G>A p.R2198H | Missense Mutation (SNP) | VAF 45/106 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs375935636; ClinVar: uncertain significance; called by muse, varscan2
- TBC1D10B | c.2323C>G p.Q775E | Missense Mutation (SNP) | VAF 53/228 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.027); catalogued as rs755020097; called by muse, mutect2, varscan2
- TCL1A | c.113C>T p.T38I | Missense Mutation (SNP) | VAF 67/166 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs201228671, COSV68085105, COSV68085114, COSV68085683; called by muse, mutect2, varscan2
- APAF1 | c.3223G>C p.G1075R (on ENST00000551964 / NM_181861.2; = p.G1021R on NM_001160.3) | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.542); called by muse, mutect2, varscan2
- APP | c.121C>A p.L41M | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ASXL3 | c.4936C>G p.H1646D | Missense Mutation (SNP) | VAF 13/145 reads (9%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.342); called by muse, mutect2
- BCAR3 | c.1765C>A p.P589T | Missense Mutation (SNP) | VAF 14/99 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CD22 | c.86del p.P29Lfs*21 | Frame Shift Del (DEL) | VAF 32/133 reads (24%) | called by mutect2, pindel, varscan2
- CLTC | c.1295C>T p.S432F | Missense Mutation (SNP) | VAF 10/134 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.01); called by muse, mutect2
- COLEC11 | c.553G>T p.A185S | Missense Mutation (SNP) | VAF 16/160 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.088); called by muse, mutect2
- DNHD1 | c.13651T>C p.W4551R | Missense Mutation (SNP) | VAF 18/215 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- DOCK7 | c.136C>T p.H46Y | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.026); called by muse, mutect2
- DSG2 | c.2041C>A p.L681I | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.43); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- EDRF1 | c.1516T>C p.Y506H (on ENST00000356792 / NM_001202438.2; = p.Y472H on NM_015608.2) | Missense Mutation (SNP) | VAF 16/25 reads (64%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); called by muse, mutect2, varscan2
- EIF2S3B | c.1265C>A p.A422D | Missense Mutation (SNP) | VAF 19/284 reads (7%) | SIFT tolerated (0.48); PolyPhen probably damaging (0.995); called by muse, mutect2
- H2BC7 | c.26C>T p.P9L | Missense Mutation (SNP) | VAF 88/235 reads (37%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- HSPA2 | c.907G>A p.A303T | Missense Mutation (SNP) | VAF 6/87 reads (7%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.885); called by muse, mutect2
- IGHV2-70D | c.274A>C p.K92Q | Missense Mutation (SNP) | VAF 47/81 reads (58%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.59); called by muse, varscan2
- KIAA1522 | c.545C>T p.A182V (on ENST00000373480 / NM_001198972.2; = p.A241V on NM_020888.3) | Missense Mutation (SNP) | VAF 60/127 reads (47%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2, varscan2
- KNL1 | c.3688G>T p.D1230Y (on ENST00000346991 / NM_170589.5; = p.D1204Y on NM_144508.5) | Missense Mutation (SNP) | VAF 179/391 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.799); called by muse, mutect2, varscan2
- NEFM | c.1534C>A p.P512T | Missense Mutation (SNP) | VAF 17/150 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.003); called by muse, mutect2
- PDIA2 | c.1303T>G p.Y435D | Missense Mutation (SNP) | VAF 28/211 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- STXBP5L | c.1414T>C p.S472P | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.375); called by muse, mutect2
- SYNPO2 | c.2161C>T p.R721W | Missense Mutation (SNP) | VAF 89/311 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.712); called by muse, mutect2, varscan2
- SYT17 | c.97A>T p.K33* | Nonsense Mutation (SNP) | VAF 9/36 reads (25%) | called by mutect2, varscan2
- TBC1D23 | c.1545del p.V516Wfs*20 (on ENST00000394144 / NM_001199198.3; = p.V516Wfs*5 on NM_018309.5) | Frame Shift Del (DEL) | VAF 12/67 reads (18%) | called by mutect2, pindel, varscan2
- TRPV3 | c.422A>C p.E141A | Missense Mutation (SNP) | VAF 40/161 reads (25%) | SIFT tolerated (0.4); PolyPhen benign (0.332); called by muse, mutect2, varscan2
- TRPV3 | c.421G>A p.E141K | Missense Mutation (SNP) | VAF 41/164 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0.26); called by muse, mutect2, varscan2
- TUBB4A | c.103A>C p.T35P | Missense Mutation (SNP) | VAF 101/376 reads (27%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.251); called by muse, mutect2, varscan2
- VAV3 | c.443T>C p.I148T | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.603); called by muse, mutect2, varscan2
- AFF1 | c.1959C>A p.A653= | Silent (SNP) | VAF 141/244 reads (58%) | catalogued as rs116543050; called by muse, mutect2, varscan2
- C3orf80 | c.648C>G p.P216= | Silent (SNP) | VAF 62/121 reads (51%) | catalogued as rs1238787906; called by muse, mutect2, varscan2
- CD82 | c.174C>T p.V58= | Silent (SNP) | VAF 35/363 reads (10%) | called by muse, mutect2
- FUT10 | c.522C>T p.S174= | Silent (SNP) | VAF 79/241 reads (33%) | catalogued as rs1280482905; called by muse, mutect2, varscan2
- FUT3 | c.843C>T p.Y281= | Silent (SNP) | VAF 33/61 reads (54%) | catalogued as rs765480346, COSV99744216; called by muse, mutect2, varscan2
- GMCL2 | c.1258C>T p.L420= | Silent (SNP) | VAF 39/526 reads (7%) | called by muse, mutect2
- GOLM2 | c.351G>A p.S117= | Silent (SNP) | VAF 48/430 reads (11%) | catalogued as rs780302499, COSV55462203; called by muse, mutect2, varscan2
- HSPA8 | c.969T>C p.D323= | Silent (SNP) | VAF 46/78 reads (59%) | called by muse, mutect2, varscan2
- IGHV2-70D | c.156A>G p.G52= | Silent (SNP) | VAF 34/84 reads (40%) | called by muse, varscan2
- KRT76 | c.681C>T p.P227= | Silent (SNP) | VAF 8/36 reads (22%) | called by muse, mutect2, varscan2
- MMP21 | c.654C>T p.A218= | Silent (SNP) | VAF 90/183 reads (49%) | called by muse, mutect2, varscan2
- MYBPC2 | c.3342C>T p.D1114= | Silent (SNP) | VAF 10/153 reads (7%) | catalogued as rs760048751, COSV63094431; called by muse, mutect2
- PIM1 | c.90G>A p.E30= | Silent (SNP) | VAF 47/129 reads (36%) | catalogued as rs537732412; called by muse, mutect2, varscan2
- SCCPDH | c.924T>G p.L308= | Silent (SNP) | VAF 14/114 reads (12%) | called by muse, mutect2, varscan2
- SHPRH | c.4437C>T p.R1479= (on ENST00000275233 / NM_001042683.3; = p.R1483= on NM_173082.3) | Silent (SNP) | VAF 47/167 reads (28%) | called by muse, mutect2, varscan2
- SULT1B1 | c.603A>G p.P201= | Silent (SNP) | VAF 4/18 reads (22%) | called by muse, varscan2
- TAF6L | c.1299T>C p.L433= | Silent (SNP) | VAF 21/265 reads (8%) | called by muse, mutect2
- TCL1A | c.114C>G p.T38= | Silent (SNP) | VAF 68/165 reads (41%) | catalogued as COSV68086108; called by muse, mutect2, varscan2
- TUBA1A | c.1311G>C p.V437= | Silent (SNP) | VAF 33/300 reads (11%) | called by muse, mutect2, varscan2
- VWF | c.1722G>A p.P574= | Silent (SNP) | VAF 17/38 reads (45%) | catalogued as rs368329035; called by muse, mutect2, varscan2
- ABCF2 | c.*811_*822del | 3'UTR (DEL) | VAF 13/85 reads (15%) | called by mutect2, pindel, varscan2
- AC025278.2 | n.87G>A | RNA (SNP) | VAF 7/33 reads (21%) | called by muse, mutect2, varscan2
- ANKS1B | c.2420-109T>C | Intron (SNP) | VAF 23/43 reads (53%) | catalogued as rs1266732712, COSV60363823; called by muse, mutect2, varscan2
- ARHGEF15 | c.989+15del | Intron (DEL) | VAF 10/24 reads (42%) | called by mutect2, pindel, varscan2
- ASAP1 | c.*1437G>A | 3'UTR (SNP) | VAF 9/87 reads (10%) | called by muse, mutect2, varscan2
- ASB16 | c.570-164C>G | Intron (SNP) | VAF 3/37 reads (8%) | called by muse, mutect2
- BCL7A | c.-37G>C | 5'UTR (SNP) | VAF 5/32 reads (16%) | catalogued as rs1468960779; called by muse, mutect2
- C5orf49 | chr5:7851283 C>T | 5'Flank (SNP) | VAF 63/289 reads (22%) | called by muse, mutect2, varscan2
- CCL16 | c.*51A>G | 3'UTR (SNP) | VAF 65/158 reads (41%) | catalogued as rs754829277; called by muse, mutect2, varscan2
- CCT4 | chr2:61888739 C>T | 5'Flank (SNP) | VAF 20/82 reads (24%) | called by muse, varscan2
- CERT1 | c.87-44C>T | Intron (SNP) | VAF 20/524 reads (4%) | catalogued as rs981428149; called by muse, mutect2
- CSNK2B | c.367+32G>A | Intron (SNP) | VAF 62/200 reads (31%) | catalogued as rs368195940; called by muse, mutect2, varscan2
- CSRNP3 | c.*6803C>A | 3'UTR (SNP) | VAF 43/93 reads (46%) | called by muse, mutect2, varscan2
- DCX | c.*5441G>A | 3'UTR (SNP) | VAF 7/40 reads (18%) | catalogued as rs751638117; called by muse, mutect2, varscan2
- DHRS4 | c.722+45G>A | Intron (SNP) | VAF 114/312 reads (37%) | called by muse, mutect2, varscan2
- DPH6 | c.*444G>A | 3'UTR (SNP) | VAF 21/75 reads (28%) | catalogued as rs777696440; called by mutect2, varscan2
- FAM110C | c.*1663G>T | 3'UTR (SNP) | VAF 34/73 reads (47%) | called by muse, mutect2, varscan2
- FANCC | c.*2298C>T | 3'UTR (SNP) | VAF 13/113 reads (12%) | catalogued as rs918489083; called by muse, mutect2, varscan2
- FBXO9 | c.-29A>G | 5'UTR (SNP) | VAF 26/268 reads (10%) | called by muse, mutect2
- FOXP3 | c.*427C>T | 3'UTR (SNP) | VAF 17/87 reads (20%) | catalogued as rs1343700950; called by muse, mutect2, varscan2
- FSD2 | c.*2987C>T | 3'UTR (SNP) | VAF 25/189 reads (13%) | called by muse, mutect2, varscan2
- G3BP1 | c.*8104C>T | 3'UTR (SNP) | VAF 14/85 reads (16%) | called by muse, mutect2, varscan2
- GPA33 | c.*19C>T | 3'UTR (SNP) | VAF 24/60 reads (40%) | catalogued as rs372035414; called by muse, mutect2, varscan2
- HAND2 | c.-45G>A | 5'UTR (SNP) | VAF 3/31 reads (10%) | catalogued as rs1449811113; called by muse, mutect2
- IMPACT | c.*1258T>A | 3'UTR (SNP) | VAF 4/45 reads (9%) | called by muse, mutect2
- JADE2 | c.*2362T>C | 3'UTR (SNP) | VAF 32/153 reads (21%) | called by muse, mutect2, varscan2
- LHFPL6 | c.*150A>G | 3'UTR (SNP) | VAF 11/108 reads (10%) | called by muse, mutect2, varscan2
- LILRB5 | c.1475-71G>A | Intron (SNP) | VAF 4/18 reads (22%) | catalogued as rs983548164; called by muse, mutect2
- MACROD2 | c.*15G>A | 3'UTR (SNP) | VAF 50/210 reads (24%) | catalogued as rs751796677, COSV99425852; called by muse, mutect2, varscan2
- MMEL1 | c.233-32C>A | Intron (SNP) | VAF 8/45 reads (18%) | called by muse, mutect2, varscan2
- MN1 | c.*2203C>T | 3'UTR (SNP) | VAF 20/40 reads (50%) | catalogued as rs767532248; called by muse, mutect2, varscan2
- NAA15 | c.*1763T>G | 3'UTR (SNP) | VAF 23/130 reads (18%) | called by muse, mutect2, varscan2
- NEK6 | c.*205T>G | 3'UTR (SNP) | VAF 20/83 reads (24%) | called by muse, mutect2, varscan2
- NOS3 | c.1752+967G>A | Intron (SNP) | VAF 11/35 reads (31%) | catalogued as rs1272835366; called by muse, mutect2, varscan2
- PALLD | c.2622+69A>G | Intron (SNP) | VAF 6/47 reads (13%) | called by muse, mutect2, varscan2
- PANK3 | c.*2746C>T | 3'UTR (SNP) | VAF 26/100 reads (26%) | called by muse, mutect2, varscan2
- QSOX1 | c.*3624G>A | 3'UTR (SNP) | VAF 33/79 reads (42%) | called by muse, mutect2, varscan2
- RNF213 | c.*1476A>G | 3'UTR (SNP) | VAF 50/121 reads (41%) | called by muse, mutect2, varscan2
- RPL22L1 | c.*21G>A | 3'UTR (SNP) | VAF 13/234 reads (6%) | called by muse, mutect2
- SIAH1 | c.-88C>T | 5'UTR (SNP) | VAF 5/41 reads (12%) | catalogued as rs1419740537; called by muse, mutect2
- UQCRQ | chr5:132867822 C>T | 3'Flank (SNP) | VAF 5/73 reads (7%) | called by muse, mutect2
- XIST | n.8159C>A | RNA (SNP) | VAF 74/78 reads (95%) | called by muse, mutect2, varscan2
- ZNF260 | c.*252A>G | 3'UTR (SNP) | VAF 20/74 reads (27%) | called by muse, mutect2, varscan2
